Surgical pathology report (de-identified scan), TCGA case TCGA-HV-A5A6, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HV-A5A6-01A (Primary Tumor).

Pancreas Cancer

<Slide key: A: pancreatic resection margin, B: #13, C: LN #14, D: omentum,
E: LN #5, F: LN #8, G: LN #12, H: LN 13#, I: LN 16#, 1: , 2-5: duodenum
(2: ampulla of vater, 3
6: duodenur 7-8: CBD
9: CBI 0-11: GB (10: CBD opening , 12:
13: ampulla of vater

MICRO (25 HE)

DIAGNOSIS:

Head of pancreas, duodenum, common bile duct and gallbladder,
pylorus-preserving pancreaticoduodenectomy:

- Ductal adenocarcinoma, well differentiated, pancreas
- with 1) tumor size: 3.5x2.3cm
- 2) extension to peripancreatic soft tissue
- 3) invasion to duodenum, common bile duct and ampulla of Vater
- 4) perineural invasion, multifocal
- 5) venous invasion: not identified
- 6) clear pancreatic, common bile duct and duodenal resection margins
- 7) metastasis to two out of 22 regional lymph nodes
(LN #13: 0/4, LN #14: 0/1, LN #5: 0/0, LN #8: 0/2, LN #12: 0/11,
LN #16: 0/13, peripancreatic LN: 1/1)
- 8) pathologic staging: pT3 N1b

ICD-0-3

adenocarcinoma, duct, NOS 8500/3
Path Site: pancreas, NOS c25.9
CQIF pancreas, head c25.0

hw 12/10/12

Source: NCI Genomic Data Commons file f19fbd51-8344-43e2-9b31-9b10635c2c8c (TCGA-HV-A5A6.6C6BDA2E-3A76-4EEB-99FB-6D1C4B8D5DBF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).